Somatic mutation profile of tumor specimen MP2PRT-PAPFHC-TMP1-A (aliquot MP2PRT-PAPFHC-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPFHC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,689 days).
Specimen MP2PRT-PAPFHC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e4d6869-1817-48fd-ba2d-7527437b19d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPFHC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPFHC-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06a26636-ffa4-43de-a4ff-73988627d159

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, 5'UTR 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS10 | c.1964C>T p.A655V | Missense Mutation (SNP) | VAF 195/652 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs573956702, COSV54354389; called by muse, mutect2, varscan2
- DDX5 | c.306T>G p.P102= | Splice Region (SNP) | VAF 110/353 reads (31%) | catalogued as rs1055839920; called by muse, mutect2, varscan2
- DRD2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 138/495 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201724929, COSV60762454; called by muse, mutect2, varscan2
- EPHB1 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 155/575 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as rs762457030, COSV67653944, COSV67656557, COSV67663588; called by muse, mutect2, varscan2
- FOXN1 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 198/629 reads (31%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.308); catalogued as rs752348608; called by muse, varscan2
- HTRA1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 77/375 reads (21%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.82); catalogued as rs765112668, COSV64564070; called by muse, mutect2, varscan2
- CTTNBP2NL | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 87/318 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- GLDN | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 125/415 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGLV5-45 | chr22:22376502 TTCTCACAGT>CTTACAG | Missense Mutation (DEL) | VAF 83/350 reads (24%) | called by pindel, varscan2*
- RAG1 | c.2419_2424del p.F807_Y808del | In Frame Del (DEL) | VAF 60/405 reads (15%) | called by pindel*, varscan2
- FAM209B | c.273A>G p.R91= | Silent (SNP) | VAF 89/303 reads (29%) | called by muse, mutect2, varscan2
- IGHV4-59 | c.349del p.*117= | Silent (DEL) | VAF 53/183 reads (29%) | called by pindel*, varscan2
- PTPRN2 | c.258G>A p.L86= | Silent (SNP) | VAF 188/639 reads (29%) | called by muse, mutect2, varscan2
- RB1CC1 | c.1542G>A p.R514= | Silent (SNP) | VAF 87/258 reads (34%) | catalogued as rs1309743208; called by muse, mutect2, varscan2
- C4orf50 | c.-46T>A | 5'UTR (SNP) | VAF 119/443 reads (27%) | called by muse, mutect2, varscan2
